Somatic mutation profile of tumor specimen C3N-00579-02 (aliquot CPT0069520009) from CPTAC case C3N-00579, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.8 years (24,755 days).
Specimen C3N-00579-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46f841a2-133f-41e9-aea4-4b8ebd3273d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00579-71 (Blood Derived Normal), aliquot CPT0069630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92360e0f-889d-4c4e-9f6a-4ee29800a0ff

The open-access MAF lists 90 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 16, Nonsense Mutation 7, Intron 4, Frame Shift Del 4, Splice Site 3, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 188/762 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 70/281 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3005-1G>A p.X1002_splice | Splice Site (SNP) | VAF 57/303 reads (19%) | catalogued as CS066265, COSV100068458; called by muse, mutect2, varscan2
- CCT7 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758087336; called by muse, mutect2, varscan2
- CEACAM20 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs372851437; called by muse, mutect2, varscan2
- CYLC1 | c.419del p.T140Kfs*8 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV100254846; called by mutect2, pindel, varscan2
- DENND1A | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.154); catalogued as rs1037729488; called by muse, mutect2, varscan2
- DISP1 | c.4105del p.I1369Lfs*13 | Frame Shift Del (DEL) | VAF 55/404 reads (14%) | catalogued as rs776640172; called by mutect2, varscan2
- DNAH5 | c.9493C>T p.Q3165* | Nonsense Mutation (SNP) | VAF 69/669 reads (10%) | catalogued as COSV54251491; called by muse, mutect2, varscan2
- FRAS1 | c.5719C>T p.Q1907* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as COSV53604200; called by muse, mutect2, varscan2
- GOLGA8H | c.1459A>T p.R487* | Nonsense Mutation (SNP) | VAF 194/685 reads (28%) | catalogued as rs1360372803; called by muse, mutect2, varscan2
- HIVEP3 | c.6017C>T p.S2006L | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1383981325; called by muse, mutect2, varscan2
- HS3ST1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs747592027; called by muse, mutect2, varscan2
- ICE1 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1231495459; called by muse, mutect2, varscan2
- IPO4 | c.1757+1G>T p.X586_splice | Splice Site (SNP) | VAF 20/139 reads (14%) | catalogued as rs565149791; called by muse, mutect2, varscan2
- JRKL | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757660425; called by muse, mutect2, varscan2
- KDM2A | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV67080951; called by muse, mutect2
- LPGAT1 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.97); catalogued as rs1323316657; called by muse, mutect2
- MAPK4 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs768874032, COSV101245310, COSV101245513; called by muse, mutect2, varscan2
- NFATC2IP | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV57911624; called by muse, mutect2
- NOX5 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs995095561, COSV52995647; called by muse, mutect2, varscan2
- OR6V1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs183152674; called by muse, mutect2
- PACSIN1 | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99762904; called by muse, mutect2, varscan2
- PALLD | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767187687; called by muse, mutect2, varscan2
- RB1 | c.2370C>G p.Y790* | Nonsense Mutation (SNP) | VAF 72/308 reads (23%) | catalogued as CM011479, CM034906, COSV57311810; called by muse, varscan2
- SH3TC1 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1309187912, COSV55283454; called by muse, mutect2, varscan2
- SHISA3 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 55/312 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1293945694; called by muse, mutect2, varscan2
- SPTAN1 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 92/462 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.298); catalogued as rs201168391, COSV63989243; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SSH3 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs1043358584; called by muse, mutect2, varscan2
- TGM7 | c.1069T>C p.W357R | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs910516311; called by muse, mutect2, varscan2
- TNXB | c.12319T>C p.F4107L (on ENST00000647633; = p.F3860L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs1462345615; called by mutect2, varscan2
- VWA5B2 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs867908315; called by muse, mutect2, varscan2
- ABCA13 | c.5711C>T p.S1904F | Missense Mutation (SNP) | VAF 104/639 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.2354C>A p.A785D | Missense Mutation (SNP) | VAF 115/703 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANPEP | c.2747A>C p.Q916P | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CACNA2D3 | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by mutect2, varscan2
- DNAH12 | c.3415C>T p.Q1139* (on ENST00000351747; = p.Q1162* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | called by muse, varscan2
- ELK3 | c.510del p.E171Kfs*12 | Frame Shift Del (DEL) | VAF 121/647 reads (19%) | called by mutect2, pindel, varscan2
- EPOR | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 23/633 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- F2 | c.204G>C p.E68D | Missense Mutation (SNP) | VAF 53/379 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM171A2 | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- GABBR1 | c.2156G>T p.G719V | Missense Mutation (SNP) | VAF 87/340 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- GRM8 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GTF3C5 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KAT2B | c.774G>T p.W258C | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LHFPL3 | c.387G>C p.W129C | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- LRP2 | c.3935G>A p.C1312Y | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.29662A>G p.T9888A | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- NUMB | c.857A>G p.K286R (on ENST00000355058; = p.K275R on NM_003744.5) | Missense Mutation (SNP) | VAF 147/579 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- OR10G7 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2F1 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- OR5M8 | c.602T>A p.V201E | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- OTUD7A | c.2684G>A p.R895Q (on ENST00000307050 / NM_001382637.1; = p.R888Q on NM_130901.3) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PPARA | c.369+1G>A p.X123_splice | Splice Site (SNP) | VAF 108/482 reads (22%) | called by muse, mutect2, varscan2
- PRPS1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SCN2A | c.4914_4933del p.L1639Dfs*17 | Frame Shift Del (DEL) | VAF 64/489 reads (13%) | called by mutect2, pindel
- SLCO1C1 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SOX11 | c.1321dup p.Y441Lfs*61 | Frame Shift Ins (INS) | VAF 10/94 reads (11%) | called by mutect2, pindel
- SSH3 | c.1892G>C p.G631A | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TAP1 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 138/485 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- TECPR2 | c.2499C>G p.F833L | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2
- TMEM94 | c.252C>A p.C84* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- TRPM6 | c.5149A>G p.N1717D | Missense Mutation (SNP) | VAF 53/460 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TTN | c.50900G>C p.G16967A (on ENST00000591111; = p.G9543A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | PolyPhen probably damaging (0.999); called by muse, varscan2
- ZC3H11A | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZCCHC7 | c.1040T>A p.L347* | Nonsense Mutation (SNP) | VAF 45/315 reads (14%) | called by muse, mutect2, varscan2
- ABCC10 | c.3274C>T p.L1092= (on ENST00000372530 / NM_001198934.2; = p.L1064= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 93/408 reads (23%) | called by muse, mutect2, varscan2
- APOB | c.3897T>G p.P1299= | Silent (SNP) | VAF 44/239 reads (18%) | called by muse, mutect2, varscan2
- CDH26 | c.1161G>C p.V387= | Silent (SNP) | VAF 147/1085 reads (14%) | catalogued as COSV99722735; called by muse, mutect2, varscan2
- DCP1A | c.126C>T p.A42= | Silent (SNP) | VAF 20/86 reads (23%) | called by muse, varscan2
- EMSY | c.3147G>C p.V1049= | Silent (SNP) | VAF 53/430 reads (12%) | called by muse, mutect2, varscan2
- GALNT8 | c.15G>A p.R5= | Silent (SNP) | VAF 25/324 reads (8%) | called by muse, mutect2
- GPR152 | c.801C>G p.V267= | Silent (SNP) | VAF 25/342 reads (7%) | called by muse, mutect2
- GRIN2A | c.3792G>A p.E1264= | Silent (SNP) | VAF 117/925 reads (13%) | catalogued as COSV58052253; called by muse, mutect2, varscan2
- IGLON5 | c.669G>A p.V223= | Silent (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- MDGA2 | c.636T>C p.G212= | Silent (SNP) | VAF 46/152 reads (30%) | called by muse, varscan2
- OBSCN | c.21534C>T p.S7178= | Silent (SNP) | VAF 41/368 reads (11%) | called by muse, mutect2, varscan2
- OXCT1 | c.57A>C p.G19= | Silent (SNP) | VAF 64/705 reads (9%) | called by muse, mutect2
- PARD3B | c.1650G>A p.L550= | Silent (SNP) | VAF 11/250 reads (4%) | called by muse, mutect2
- PRUNE2 | c.1284C>T p.S428= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs367937883; called by muse, mutect2, varscan2
- SLC13A3 | c.1425C>T p.I475= | Silent (SNP) | VAF 40/212 reads (19%) | catalogued as rs147641404, COSV51714483; called by muse, mutect2, varscan2
- TMC6 | c.1689C>T p.D563= | Silent (SNP) | VAF 99/599 reads (17%) | called by muse, mutect2, varscan2
- ACADM | c.-78G>C | 5'UTR (SNP) | VAF 7/62 reads (11%) | catalogued as rs908019570, COSV100897826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL353753.1 | n.617T>A | RNA (SNP) | VAF 69/204 reads (34%) | called by muse, mutect2, varscan2
- GGTLC2 | chr22:22644038 G>A | 5'Flank (SNP) | VAF 24/137 reads (18%) | called by mutect2, varscan2
- HBE1 | c.-267+102339C>G | Intron (SNP) | VAF 18/277 reads (6%) | catalogued as rs754544315; called by muse, mutect2
- PXN | c.831+1958C>T | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- RP1L1 | c.609+829G>A | Intron (SNP) | VAF 72/240 reads (30%) | catalogued as rs368905054; called by muse, varscan2
- SH2D2A | c.123+209C>T | Intron (SNP) | VAF 27/460 reads (6%) | called by muse, mutect2
- SPINK7 | c.*26G>C | 3'UTR (SNP) | VAF 6/129 reads (5%) | catalogued as COSV99199134; called by muse, mutect2
